TARGET case TARGET-00-SJNORM016314 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/44705686-1345-48aa-908e-26c6de8be14c

Biospecimens (5 samples)
- Samples TARGET-00-SJNORM016314-17A.1, TARGET-00-SJNORM016314-17A.2, TARGET-00-SJNORM016314-17A.3, TARGET-00-SJNORM016314-17A.4, TARGET-00-SJNORM016314-17A.5 (5 with the same recorded description): Sample type: Lymphoid Normal; Tissue type: Normal; Specimen type: Lymphoid.
